Surgical pathology report (de-identified scan), TCGA case TCGA-ED-A97K, project TCGA-LIHC (Liver Hepatocellular Carcinoma), tissue source site Asterand, specimen TCGA-ED-A97K-01A (Primary Tumor).

TSS Patient ID:

Surgical Date:

Gross Description: Tumor is ill-margins, solid and firm, gray-white in cutting section with 5x4x4cm in size.

Microscopic Description: Tumor cells form the trabecular patterns or cords or tubules or adenoids patterns intervening in benign tissue. Tumor invades into fibrous stroma. The amount of cytoplasm are abundant and the cytoplasm is clear or basophilic. Nuclei are irregularly large and hyperchromatic with prominent nucleoli. Mitoses are present. Tumor is invasion of inflammatory cells and necrotic. Stroma is marked fibrous and hyaline.

Diagnosis Details: Hepatocellular carcinoma and cholangiocarcinoma, combined

Comments:

Formatted Path Reports: LIVER TISSUE CHECKLIST

Specimen type: Wedge resection, lobectomy

Tumor size: 5 x 4 x 4 cm

Focality: Not specified

Histologic type: Hepatocellular carcinoma and cholangiocarcinoma, combined

Histologic grade: Moderately differentiated

Tumor extent: Not specified

Lymph nodes: Not specified

Venous invasion: Not specified

Margins: Uninvolved

Evidence of neo-adjuvant treatment: No

Additional pathologic findings: Not specified

Comments: None

C&F

ICD-O-3

Hepatobiliary carcinoma

8180/3

Carcinoma hepatocellular & cholangiocarcinoma combined 8180/3

Site: Liver C22.0

4/7/14

Source: NCI Genomic Data Commons file f3ca9065-106d-489e-a6b5-a35a9efb9cb2 (TCGA-ED-A97K.518E0619-1C4F-475C-904E-009300CF1768.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).